Somatic mutation profile of tumor specimen C3L-06642-01 (aliquot CPT0358700006) from CPTAC case C3L-06642, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,049 days).
Specimen C3L-06642-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76a13c35-c112-4bc4-b488-ef4e38ae58f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06642-31 (Blood Derived Normal), aliquot CPT0358790005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67996be3-d409-4ee7-8818-134f35d20052

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, 3'UTR 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 45/195 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69041945; called by muse, mutect2, varscan2
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 45/260 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSF | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as rs772387265, COSV63839171; called by muse, mutect2, varscan2
- BMP5 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs758682018, COSV63702200; called by muse, mutect2, varscan2
- BTRC | c.559C>T p.R187W (on ENST00000370187 / NM_033637.4; = p.R151W on NM_003939.5) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1165056261; called by muse, mutect2, varscan2
- ENO4 | c.499G>A p.A167T (on ENST00000622726; = p.A166T on NM_001242699.2) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.063); catalogued as rs368025714, COSV58005750; called by muse, mutect2, varscan2
- EPHA5 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56665723; called by muse, mutect2, varscan2
- FAM117A | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 66/482 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs368699234; called by muse, mutect2, varscan2
- HAS1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs530794115, COSV55785948; called by muse, mutect2, varscan2
- KAT8 | c.823A>C p.T275P | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99571951; called by muse, mutect2, varscan2
- KIF18A | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.534); catalogued as rs776978896; called by muse, mutect2, varscan2
- LRIG1 | c.2317C>T p.R773* | Nonsense Mutation (SNP) | VAF 53/468 reads (11%) | catalogued as COSV56244981; called by muse, mutect2, varscan2
- MKRN3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1461939355, COSV58808468, COSV58808530; called by muse, mutect2, varscan2
- NYNRIN | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs751312331, COSV101230655; called by muse, mutect2, varscan2
- PAX1 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68273586; called by muse, mutect2, varscan2
- PTCHD4 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 28/201 reads (14%) | catalogued as rs910334387, COSV59777413; called by muse, mutect2, varscan2
- RBBP8 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs370311825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC5 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.818); catalogued as rs757275164, COSV55778499; called by muse, mutect2, varscan2
- TMEFF2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as rs149067350; called by muse, mutect2
- ZFHX4 | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV51454206, COSV51471359, COSV99257900; called by muse, mutect2, varscan2
- ZNF648 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60569817; called by muse, mutect2, varscan2
- ABCB4 | c.2261T>A p.F754Y | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- ATG7 | c.1723A>G p.S575G | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- C4orf46 | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CD8B | c.671G>C p.G224A (on ENST00000331469 / NM_172213.4; = p.G194A on NM_172102.4) | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); called by muse, mutect2
- DZIP3 | c.2327T>G p.F776C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2
- GDF2 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- INTU | c.2345A>T p.E782V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ITGA2 | c.1294A>C p.N432H | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1522 | c.1984C>T p.P662S (on ENST00000373480 / NM_001198972.2; = p.P721S on NM_020888.3) | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB4 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1224C>G p.D408E | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- PHIP | c.1246C>G p.Q416E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLEKHM1 | c.1937A>T p.E646V | Missense Mutation (SNP) | VAF 52/552 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TSPOAP1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 28/433 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- VN1R2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 41/371 reads (11%) | PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- WNK3 | c.935C>G p.T312S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF569 | c.1727A>G p.K576R | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.247); called by muse, mutect2
- ADAMTS1 | c.102C>A p.P34= | Silent (SNP) | VAF 38/335 reads (11%) | catalogued as rs754487661; called by muse, mutect2, varscan2
- ANKFN1 | c.3249C>T p.S1083= (on ENST00000653862; = p.S936= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/369 reads (16%) | catalogued as rs1200772561; called by muse, mutect2, varscan2
- CATSPERD | c.1884G>A p.P628= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as rs745659330; called by muse, mutect2
- GRM1 | c.2346C>T p.N782= | Silent (SNP) | VAF 55/404 reads (14%) | catalogued as rs145874853; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFT140 | c.3924C>T p.T1308= | Silent (SNP) | VAF 57/427 reads (13%) | catalogued as rs773997219; called by muse, mutect2, varscan2
- ITGA8 | c.582G>A p.P194= | Silent (SNP) | VAF 30/311 reads (10%) | catalogued as rs778742435, COSV65233607; called by muse, mutect2
- JAG1 | c.2076C>T p.D692= | Silent (SNP) | VAF 51/341 reads (15%) | called by muse, mutect2, varscan2
- KCNA3 | c.1581G>A p.S527= | Silent (SNP) | VAF 19/390 reads (5%) | called by muse, mutect2
- LINGO4 | c.687G>A p.Q229= | Silent (SNP) | VAF 62/348 reads (18%) | catalogued as rs374452560; called by muse, mutect2, varscan2
- LRRN3 | c.111C>A p.I37= | Silent (SNP) | VAF 39/281 reads (14%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1759A>C p.R587= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- NTNG1 | c.777C>T p.V259= | Silent (SNP) | VAF 47/358 reads (13%) | called by muse, mutect2, varscan2
- OR2T33 | c.531C>T p.C177= | Silent (SNP) | VAF 53/259 reads (20%) | catalogued as rs746857030, COSV58815948; called by muse, mutect2, varscan2
- RAB6C | c.660G>A p.K220= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs1270729041; called by mutect2, varscan2
- RIMBP2 | c.297C>T p.S99= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as rs144527552; called by muse, mutect2, varscan2
- TAL1 | c.97C>T p.L33= | Silent (SNP) | VAF 50/393 reads (13%) | called by muse, mutect2, varscan2
- ADNP | c.*1G>C | 3'UTR (SNP) | VAF 21/172 reads (12%) | catalogued as rs1343261579; called by muse, mutect2, varscan2
- SMG7 | c.*1196C>T | 3'UTR (SNP) | VAF 53/387 reads (14%) | catalogued as rs765169448; called by muse, mutect2, varscan2
